Gene-level copy-number profile of tumor specimen C3L-01313-03 from CPTAC case C3L-01313, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 63.7 years (23,275 days).
Specimen C3L-01313-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6e564a61-d632-48b4-88fe-a9a11ac78bbb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01313-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/7d1e01ef-0476-4e03-bd91-eec96d206337

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 11; copy number 2: 9,072; copy number 3: 2,304; copy number 4: 35,103; copy number 6: 10,920; copy number 8: 1,499.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:9,053,122–9,129,752, 4 genes: CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
